Somatic mutation profile of tumor specimen TCGA-W5-AA34-01A (aliquot TCGA-W5-AA34-01A-11D-A417-09) from TCGA case TCGA-W5-AA34, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 75.4 years (27,535 days).
Specimen TCGA-W5-AA34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2283b532-8741-4b66-822d-87e5d4d1c6ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-W5-AA34-10A (Blood Derived Normal), aliquot TCGA-W5-AA34-10A-01D-A41A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab88156f-b729-4d9f-8125-25e18c68c044

The open-access MAF lists 33 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 26, Silent 6, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.827T>G p.F276C | Missense Mutation (SNP) | VAF 36/43 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60641618; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK1 | c.5329C>T p.R1777W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.394); catalogued as rs781061339; called by muse, mutect2, varscan2
- DLGAP2 | c.1899C>A p.S633R | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101420964; called by muse, mutect2, varscan2
- KCNH2 | c.3251C>T p.P1084L | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as rs762510312, COSV100060863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NOL4 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.969); catalogued as COSV52342401; called by muse, mutect2, varscan2
- PIGS | c.67_69del p.F23del | In Frame Del (DEL) | VAF 16/52 reads (31%) | catalogued as rs745340957; called by pindel, varscan2
- PPM1J | c.1196C>G p.P399R | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99588605; called by muse, mutect2
- SLC17A6 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as rs201082803; called by muse, mutect2, varscan2
- UNC5D | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs757237977, COSV99775459; called by muse, mutect2, varscan2
- VWF | c.2344C>T p.R782W | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs61748471, CM910391; ClinVar: not provided; called by muse, mutect2, varscan2
- AC068580.4 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ADGRG2 | c.2185A>G p.T729A (on ENST00000379869 / NM_001079858.3; = p.T726A on NM_005756.4) | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- AHNAK | c.12735C>G p.F4245L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- AMPD1 | c.1555G>A p.V519M | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- CHD7 | c.458C>A p.P153Q | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- GRM5 | c.1673C>G p.P558R | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HLA-DOA | c.167A>T p.Q56L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- JCHAIN | c.453A>C p.L151F | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTM1 | c.1019G>T p.S340I | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- MTUS2 | c.778C>G p.Q260E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- NKAPL | c.973G>T p.G325W | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10X1 | c.49A>T p.T17S | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2
- SLC5A1 | c.1085C>G p.T362S | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TET3 | c.3925A>T p.S1309C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, varscan2
- TRPC5 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFYVE26 | c.1940G>C p.S647T | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C16orf78 | c.297C>T p.D99= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs143423404; called by muse, mutect2, varscan2
- FSTL5 | c.513C>T p.D171= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs201353835; called by muse, mutect2, varscan2
- HYAL3 | c.51G>A p.L17= | Silent (SNP) | VAF 9/13 reads (69%) | called by muse, mutect2, varscan2
- MGAT4C | c.1371G>A p.R457= | Silent (SNP) | VAF 29/93 reads (31%) | catalogued as rs923771485, COSV59832801, COSV59834439; called by muse, mutect2, varscan2
- OR10G3 | c.618G>T p.V206= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV57809590; called by muse, mutect2, varscan2
- URI1 | c.213A>G p.K71= | Silent (SNP) | VAF 48/101 reads (48%) | catalogued as rs754233883; called by muse, mutect2, varscan2
